Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5442, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5442-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) NECK, BILATERAL LEVELS 1-4 DISSECTION:

Submandibular gland, right and left, no tumor present.

One left level 1 lymph node, no tumor present (0/1).

METASTATIC CARCINOMA IN ONE OF ELEVEN LEFT LEVEL 2A LYMPH NODES (1/11).

METASTATIC CARCINOMA IN ONE OF THREE LEFT LEVEL 2B LYMPH NODES WITH
EXTRANODAL EXTENSION (1/3).

Twenty three left level 3 and 4 lymph nodes, no tumor present (0/8 level 3, 0/15 level 4).

METASTATIC CARCINOMA IN ONE RIGHT LEVEL 1 LYMPH NODE (1/1).

METASTATIC CARCINOMA IN ONE RIGHT LEVEL 2 LYMPH NODE (0/11 LEVEL 2A, 1/6 LEVEL 2B).

Eleven right level 3 and 4 lymph nodes, no tumor present (0/5 level 3, 0/6 level 4).

(B) INFERIOR TURBINATE, RIGHT, EXCISION:

Bone and sinonasal mucosa, no tumor present.

(C) EXOSTOSIS, EXCISION:

Bone and fibroadipose tissue, no tumor present.

(D) MAXILLARY SINUS MUCOSA, EXCISION:

SINONASAL MUCOSA WITH FOCAL INVASIVE, POORLY DIFFERENTIATED CARCINOMA, INVOLVING BONE.

(E) MAXILLARY SINUS MUCOSA, RIGHT, EXCISION:

Fragments of bone and sinonasal mucosa, no tumor present.

(F) MAXILLARY SINUS INFERIOR MARGIN, LEFT, EXCISION:

BONE AND FIBROCONNECTIVE TISSUE WITH MULTIPLE FOCI OF POORLY DIFFERENTIATED CARCINOMA.

(G) LATERAL INFERIOR MARGIN, EXCISION:

BONE AND FIBROCONNECTIVE TISSUE WITH INVASIVE, POORLY DIFFERENTIATED CARCINOMA.

(H) INFERIOR TURBINATE, LEFT, EXCISION:

Bone and sinonasal mucosa, no tumor present.

(I) NASAL SEPTUM MARGIN, EXCISION:

INVASIVE, POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.

(J) BUCCAL FAT, LEFT, EXCISION:

FIBROADIPOSE TISSUE WITH A MINUTE FOCUS OF POORLY DIFFERENTIATED CARCINOMA.

(K) PALATE AND LEFT MAXILLA, EXCISION:

INVASIVE MULTIFOCAL POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH
BASALOID FEATURES(5.5cm) AND EXTENSIVE CARCINOMA IN SITU, INVOLVING BONE.

(L) MIDDLE TURBINATE, LEFT EXCISION:

Bone and sinonasal mucosa, no tumor present.

(M) PTERYGOID, RIGHT, EXCISION:

Salivary gland tissue, no tumor present.

(N) TOOTH, EXCISION:

Tooth with dental caries (gross diagnosis only).

(O) NASAL SEPTUM MARGIN, POSTERIOR, EXCISION:

POSITIVE FOR POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.

(P) ANTERIOR NASAL SEPTUM MARGIN, EXCISION:

Cartilage and soft tissue, no tumor present.

(Q) NASAL SEPTUM, EXCISION:

Bone and fibroconnective tissue, no tumor present.

[page 2 of 4]
Surgical Pathology Report

Collected
Received

Pathologist:
Case type: Surgical Case

(R) ANTERIOR SPHENOID SINUS TISSUE, EXCISION:
Nerve, fibroconnective tissue and mucus glands, no tumor present.

GROSS DESCRIPTION

(A) BILATERAL NECK DISSECTION (LEVELS 1-4) – A neck dissection specimen (22.0 x 16.0 x 1.5 cm) composed mostly of adipose tissue and bilateral submandibular glands.

Left level 1 is composed of an unremarkable submandibular gland (5.0 x 2.5 x 2.0 cm) and one unremarkable lymph node (0.8 x 0.5 x 0.4 cm).

Left level 2a has eleven unremarkable lymph nodes ranging in size from 0.2 to 1.4 x 0.9 x 0.8 cm.

Left level 2b is composed of two lymph nodes measuring 1.3 x 0.8 x 0.5 cm and 2.0 x 1.7 x 1.3 cm. Cut sections of the larger lymph node reveals it to be grossly positive for metastatic disease.

Left level 3 has nine unremarkable lymph nodes ranging in size from 0.2 to 2.0 x 0.5 x 0.5 cm.

Left level 4 has fifteen unremarkable lymph nodes ranging in size from 0.2 to 1.6 x 0.5 x 0.5 cm.

Right level 1 is composed of an unremarkable submandibular gland (5.5 x 3.0 x 1.5 cm) and four unremarkable lymph nodes ranging in size from 0.6 x 0.4 x 0.2 cm to 2.5 x 1.5 x 0.8 cm.

Right level 2a has eleven unremarkable lymph nodes ranging in size from 0.2 x 0.1 x 0.1 cm to 1.0 x 0.8 x 0.4 cm.

Right level 2b has six unremarkable lymph nodes ranging in size from 0.2 x 0.2 x 0.2 cm to 1.5 x 1.0 x 0.4 cm.

Right level 3 has five unremarkable lymph nodes ranging in size from 0.3 x 0.2 x 0.2 cm to 1.5 x 0.8 x 0.3 cm.

Right level 4 has six unremarkable lymph nodes ranging in size from 0.3 x 0.2 x 0.2 cm to 0.8 x 0.4 x 0.2 cm.

SECTION CODE: A1, one lymph node, left level 1, bisected; A2, left submandibular gland, representative section; A3, one lymph node, left level 2a, bisected; A4, four lymph nodes, left level 2a; A5, two lymph nodes, left level 2a; A6, four lymph nodes, left level 2a; A7, one lymph node, left level 2b, bisected; A8, A9, one lymph node, left level 2b, serially sectioned; A10, four lymph nodes, left level 3; A11, two lymph nodes, left level 3, bisected; A12, one lymph node, left level 3; A13, two lymph nodes, left level 3; A14, four lymph nodes, left level 4; A15, five lymph nodes, left level 4; A16, four lymph nodes, left level 4; A17, two lymph nodes, left level 4; A18, three lymph nodes, right level 1; A19, A20, one lymph node, right level 1, serially sectioned; A21, right submandibular gland, representative section; A22, three lymph nodes, right level 2a; A23, four lymph nodes, right level 2a; A24, two lymph nodes, right level 2a; A25, two lymph nodes, right level 2a; A26, four lymph nodes, right level 2b; A27, two lymph nodes, right level 2b; A28, two lymph nodes, right level 3; A29, three lymph nodes, right level 3; A30, four lymph nodes, right level 4; A31, two lymph nodes, right level 4.

(B) RIGHT INFERIOR TURBINATE - A 4.0 x 1.5 x 0.6 cm fragment of turbinate. The specimen is submitted in toto in B1-B2 for decalcification.

(C) EXOSTOSIS - A fragment of bone measuring 0.8 x 0.6 x 0.4 cm. The specimen is submitted in toto for decalcification.

(D) MUCOSA MAXILLARY SINUS - A 4.0 x 1.0 x 0.3 cm fragment of fibroconnective tissue. The specimen is unremarkable. The specimen is submitted in toto in D1-D2.

(E) MUCOSA MAXILLARY SINUS, RIGHT - An irregular fragment of fibroconnective tissue admixed with blood clot measuring 3.0 x 2.0 x 0.8 cm. A tiny fragment of bone is identified. The specimen is submitted in toto in E1-E2 (E2 submitted for decalcification).

[page 3 of 4]
Surgical Pathology Report

Collected:

Pathologist:

Received:

Case type: Surgical Case

(F) LEFT MAXILLARY SINUS INFERIOR MARGIN - Multiple fragments of bone measuring 1.0 x 0.8 x 0.6 cm in aggregate. The specimen is submitted in toto in F for decalcification.

(G) LATERAL INFERIOR MARGIN - A fragment of bone covered with mucosa measuring 1.5 x 1.0 x 0.4 cm. The specimen is submitted in toto in G for decalcification.

(H) LEFT INFERIOR TURBINATE - A 4.0 x 1.0 x 1.0 cm portion of turbinate. The specimen is bisected and submitted in toto in H1-H2 for decalcification.

(I) NASAL SEPTUM MARGIN - A single cartilaginous specimen, 1.5 x 0.3 x 0.2 cm is submitted entirely for frozen section in I1 and I2 and for permanent in I3.

*FS/DX: INVASIVE SQUAMOUS CELL CARCINOMA.

(J) LEFT BUCCAL FAT - A 4.0 x 2.0 x 1.0 cm fragment of yellow-tan lobulated fat tissue. The specimen is submitted in toto in J1-J2.

(K) TOTAL PALATECTOMY AND LEFT MAXILLECTOMY - A palatectomy with bone and soft tissue and teeth measuring 8.0 x 6.5 x 3.5 cm. A fungating irregular and papillomatous mass is noted occupying the roof of the mouth and extending through the soft tissue upward. The mass measures 5.5 x 4.5 x 2.0 cm. The rim of normal appearing mucosa is surrounding the mass. The mass is involving the anterior gum and dissection between the teeth. No gross involvement of the mucosal margin is noted and the tumor appears to extend superiorly, especially on the left side of the nose. The tumor invades through the left bony rim of the palate and extends into the soft tissue of the nose and the septum grossly. The specimen is submitted from left to right under K1-K28 including soft tissue protruding from the roof of the specimen.

(L) LEFT MIDDLE TURBINATE - A 3.0 x 0.5 x 0.4 cm portion of turbinate. The specimen is submitted in toto in L for decalcification.

(M) RIGHT PTERYGOID - A 1.5 x 1.0 x 0.8 cm fragment of dense fibroconnective tissue. The specimen is bisected and submitted in toto in M.

(N) TOOTH - A 2.5 x 1.0 x 0.8 cm decayed tooth. This is for gross examination only.

(O) NASAL SEPTUM MARGIN, POSTERIOR - submitted entirely for frozen section in O1-O3.

*FS/DX: SQUAMOUS CARCINOMA.

(P) NASAL SEPTUM MARGIN, ANTERIOR - submitted entirely for frozen section in P.

*FS/DX: SQUAMOUS MUCOSA.

(Q) NASAL SEPTUM - A 4.0 x 0.6 x 0.4 cm fragment of bone with mucosa. The specimen is bisected and submitted in toto in Q for decalcifications.

(R) TISSUE ANTERIOR SPHENOID SINUS - Two fragments of dense fibroconnective tissue measuring 1.0 x 0.6 x 0.4 and 1.5 x 0.6 x 0.5 cm respectively. The specimen is submitted in toto in R.

CLINICAL HISTORY

None given.

SNOMED CODES

T-C4200, T-51100, T-21340, M-80703, M-80706

[page 4 of 4]
100

Source: NCI Genomic Data Commons file 602a4120-ff0a-4500-a610-202cc3b3144e (TCGA-CV-5442.5259471D-DC2F-4E90-837F-F231595C9DDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).